Gene-level copy-number profile of tumor specimen TCGA-KK-A8I4-01A from TCGA case TCGA-KK-A8I4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.9 years (23,706 days).
Specimen TCGA-KK-A8I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.6354ebfa-6f94-4ead-8e08-e90818c1d2a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A8I4-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15330aca-1ce4-4060-a7d9-410d50859979

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 6,605; copy number 2: 40,533; copy number 3: 8,564; copy number 4: 2,598; copy number 5: 1,472.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A8I4-01A-11D-A363-01): tumor purity 0.4, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:110,321,402–110,716,595, 17 genes: AC140479.5, AC140479.1, AC140479.2, LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1.
- chr14:59,181,593–59,576,812, 7 genes (within-gene range 0–1): PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175.
- chr14:61,811,974–62,605,717, 9 genes: SYT16, COX4I1P1, AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1, ATP5F1AP4.
- chr14:78,059,942–78,060,278, 1 gene: FXNP1.
- chr14:78,177,803–78,177,921, 1 gene: RNA5SP388.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,472 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,900,016–41,625,001, 16 genes, copy number 5 (within-gene range 1–5): AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4.
- chr8:51,319,577–145,066,685, 1,456 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
